CCDI case PBCAPD — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/9c78d3e2-60ab-4ff6-a036-f651c3fbf701

Demographics
Sex at birth: male; Race: asian.

Diagnoses (1)
1. Ependymoma, NOS: ICD-O-3 morphology code: 9391/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 9.6 years (3,490 days).

Biospecimens (3 samples)
- Sample 0DMKKM: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DMKKX: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DMKNA: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
